Surgical pathology report (de-identified scan), TCGA case TCGA-14-0871, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0871-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Patient: [REDACTED]
Hospital #: [REDACTED]
Clinic #: [REDACTED]
DOB/Age/Sex: [REDACTED]
Department: Neurosurgery
Physician: [REDACTED]

Specimen #: [REDACTED]
[REDACTED] HOSPITAL INPATIENT
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Date of Report: [REDACTED]

TISSUE SOURCE:

Part 1: Left parietal brain lesion
Part 2: Left parietal brain lesion - permanent
Part 3: Dura

14-0871

CLINICAL DIAGNOSIS & HISTORY:

[REDACTED] female with brain mass.

Name of operation: Craniotomy.

Pre-Operative Diagnosis: Left parietal brain lesion

Post-Operative Diagnosis: Left parietal brain lesion

INTRAOPERATIVE CONSULTATION:

FS1A: BRAIN, LEFT PARIETAL LOBE (BIOPSY, FS1A): GLIOBLASTOMA
MULTIFORME.

GROSS DESCRIPTION:

Three specimens are received labeled with the patient's name and hospital number.

1. "Left parietal brain lesion" is received unfixed for intraoperative consultation with frozen section and is a 1.2 X 1.0 X 0.3 cm portion of mucoid, focally hemorrhagic tissue. Cytologic scrape and squash preparations are made, and a portion of the specimen is submitted for frozen section. The remainder of the cryoblock is submitted in cassette "FS1A", and the remainder of the specimen is submitted in cassette "1B".

2. "Left parietal brain lesion - permanent" is received in formalin and is multiple fragments of cerebral cortex admixed with mucoid, hemorrhagic tissue, 4.0 X 4.0 X 0.3 cm in aggregate, submitted in toto in cassettes "2A" and "2B".

3. "Dura" is a portion of tan, glistening dura mater, 2.5 X 2.5 X 0.1 cm, with no mass lesion identified. The specimen is

[page 2 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
Hospital #: [REDACTED]
Clinic #: [REDACTED]

Specimen #: [REDACTED]
Date of Report [REDACTED]

[REDACTED]

GROSS DESCRIPTION (continued):

serially sectioned and submitted in toto in cassettes "3A" and "3B".

[REDACTED]

MICROSCOPIC DESCRIPTION:

Sections show an abnormal population of pleomorphic, poorly differentiated cells arranged in broad sheets and fascicles within the brain parenchyma. The malignant cells are characterized by pleomorphic, anaplastic nuclei with dense, hyperchromatic chromatin and occasionally discernable nucleoli and variable amounts of eosinophilic, often spindled, cytoplasm. Many bizarre forms are present which appear as giant, multinucleated cells. In cytologic preparations, scattered cells show poorly-formed cell processes. Numerous abnormal mitotic figures are present. Although broad areas of necrosis are seen, significant endothelial changes are not identified. Many malignant cells display eosinophilic proteinaceous cytoplasmic globules. Brown pigment deposition is also present. Special stains are performed which show the following:

Prussian blue iron stain
Fontana-Masson melanin stain
GFAP

AE1-AE3 cytokeratin stain
Mela-A
HMB-45
S-100

Desmin
Neurofilament
Synaptophysin

Positive in brown pigment
Negative
Focally positive in neoplastic cells
Negative
Negative
Negative
Focally positive in neoplastic cells
Focally positive
Focally positive
Negative

The pathologist has reviewed and interpreted the case with the fellow/resident.

[page 3 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
Hospital #: [REDACTED]
Clinic #: [REDACTED]

Specimen #: [REDACTED]
Date of Report [REDACTED]

DIAGNOSIS

BRAIN, LEFT PARIETAL LESION (BIOPSY, FS1A): POORLY DIFFERENTIATED MALIGNANT NEOPLASM (SEE COMMENT).

BRAIN, LEFT PARIETAL LESION (BIOPSY): POORLY DIFFERENTIATED MALIGNANT NEOPLASM.

DURA (BIOPSY): DURA WITH ATTACHED POORLY DIFFERENTIATED MALIGNANT NEOPLASM.

COMMENT:

Most areas of this malignant tumor show no evidence of differentiation in immunoperoxidase stains. Melanocytic differentiation is seen in one of three melanoma stains (HMB-45). Rare focal positive staining is also seen for GFAP, neurofilament and desmin. These findings, taken together with the somewhat glial appearance of this tumor, suggest that this may be a primitive neuroectodermal tumor or glioblastoma with divergent differentiation. A malignant melanoma, either primary or metastatic, can not be ruled out.

[REDACTED]

**

Tissue Committee Code: 1

[REDACTED]

ICD9 Codes:

1. 191 MALIGNANT NEOPLASM BRAIN

[REDACTED]

Source: NCI Genomic Data Commons file 6f4a5fd3-547c-4cbd-9c0a-2635b48795bb (TCGA-14-0871.3C96FFD0-6AA2-4D06-A59A-D70E79D05822.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).